Somatic mutation profile of tumor specimen TCGA-FR-A3YO-06A (aliquot TCGA-FR-A3YO-06A-11D-A23B-08) from TCGA case TCGA-FR-A3YO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-FR-A3YO-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd5a26f8-1e0b-43e2-8a67-d2f99df1bb5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A3YO-10A (Blood Derived Normal), aliquot TCGA-FR-A3YO-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3209b7d6-b224-4c8e-870b-52a1b7f24aaa

The open-access MAF lists 1,016 somatic variants for this specimen: 663 protein-altering or splice-affecting, 332 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 590, Silent 332, Nonsense Mutation 45, Splice Site 16, Splice Region 10, RNA 7, Intron 6, 3'UTR 3, 5'Flank 2, 5'UTR 2, Translation Start Site 1, In Frame Del 1.

Variants (750 of 1,016; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919_1921del p.V640_K641delinsE (on ENST00000288602 / NM_001374244.1; = p.V600_K601delinsE on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 69/160 reads (43%) | catalogued as rs397516897, COSV56060025; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, varscan2
- HNF1A | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs193922580, CM092844; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774060871, COSV51785944, COSV51799641; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 102/366 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs796053126, CM139611, COSV51835030; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1228C>T p.L410F (on ENST00000272895 / NM_173076.3; = p.L92F on NM_015657.3) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV55954555, COSV55976882; called by muse, mutect2, varscan2
- ABCA13 | c.3731C>T p.S1244L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as COSV70027223; called by muse, mutect2, varscan2
- ABCA4 | c.6103C>T p.L2035F | Missense Mutation (SNP) | VAF 90/192 reads (47%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.936); catalogued as COSV64672612; called by muse, mutect2, varscan2
- ABCB7 | c.1913C>T p.S638L (on ENST00000373394 / NM_001271696.3; = p.S639L on NM_004299.6) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53719058; called by muse, mutect2, varscan2
- ABCC3 | c.1443G>A p.M481I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV53319544; called by muse, mutect2, varscan2
- ABCC6 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750898196, COSV52742885; called by muse, mutect2, varscan2
- ABCC9 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1025600293, COSV53967191; called by muse, mutect2
- ABRAXAS2 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV53716583; called by muse, mutect2, varscan2
- AC018755.2 | c.1283-1G>A p.X428_splice | Splice Site (SNP) | VAF 11/62 reads (18%) | catalogued as rs776017036, COSV55778824, COSV99707176; called by muse, mutect2, varscan2
- AC092143.1 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59247485; called by muse, mutect2, varscan2
- AC100868.1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs372434452, COSV51839518; called by muse, mutect2, varscan2
- AC136428.1 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 61/472 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.953); catalogued as COSV101434940; called by muse, mutect2, varscan2
- ACP3 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294091242, COSV100313535, COSV60485369; called by muse, mutect2, varscan2
- ACSM6 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV58978033; called by muse, mutect2, varscan2
- ADAMTS13 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs587701622, COSV63020852; called by muse, mutect2, varscan2
- ADAMTS2 | c.3275C>T p.S1092F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV52371333; called by muse, mutect2, varscan2
- ADGRB3 | c.4053G>A p.M1351I | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53240162, COSV53257873; called by muse, mutect2, varscan2
- ADSS1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV58272901; called by muse, mutect2
- AGXT2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs760978202, COSV51485242; called by muse, mutect2, varscan2
- AK9 | c.2872C>T p.R958* | Nonsense Mutation (SNP) | VAF 29/156 reads (19%) | catalogued as COSV58140649; called by muse, mutect2, varscan2
- AKAP1 | c.68G>A p.W23* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV58469516; called by muse, mutect2, varscan2
- ALAS2 | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV58189467; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 43/276 reads (16%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALMS1 | c.8339C>T p.S2780L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs761903209, COSV52504891, COSV52507149; called by muse, mutect2, varscan2
- ALPK2 | c.5525C>T p.S1842F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64491839; called by muse, mutect2, varscan2
- AMPD3 | c.748G>A p.D250N (on ENST00000396553 / NM_001025389.2; = p.D259N on NM_000480.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs145610067; called by muse, mutect2
- ANKLE1 | c.875C>T p.P292L (on ENST00000394458; = p.P238L on NM_152363.6) | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV63920328; called by muse, mutect2, varscan2
- ANKRD11 | c.6424C>T p.P2142S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); catalogued as rs763073381, COSV56358770; called by muse, mutect2, varscan2
- ANKRD11 | c.3469G>T p.E1157* | Nonsense Mutation (SNP) | VAF 25/215 reads (12%) | catalogued as COSV56354852, COSV56358780; called by muse, mutect2, varscan2
- ANKS1B | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.275); catalogued as COSV100247457, COSV61344160; called by muse, varscan2
- ANO4 | c.2197G>A p.A733T (on ENST00000392977 / NM_001286615.2; = p.A698T on NM_178826.4) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54591547; called by muse, varscan2
- ANTXR2 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV55018003; called by muse, mutect2, varscan2
- APEH | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1307614475, COSV56533013; called by muse, mutect2, varscan2
- APLP1 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV55702642; called by muse, mutect2, varscan2
- APLP1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV55702652; called by muse, mutect2, varscan2
- APOA4 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.222); catalogued as COSV63360288; called by muse, mutect2, varscan2
- APOB | c.12039G>A p.M4013I | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51930917; called by muse, mutect2, varscan2
- APOB | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926765; called by muse, mutect2, varscan2
- ARAF | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs200106543, COSV51692083; called by mutect2, varscan2
- ARHGEF17 | c.4695G>A p.R1565= | Splice Region (SNP) | VAF 17/32 reads (53%) | catalogued as COSV55231409; called by muse, mutect2, varscan2
- ARID2 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV57595668; called by muse, mutect2, varscan2
- ARSF | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63839305; called by muse, mutect2, varscan2
- ASIP | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs780888249, COSV66588306; called by muse, mutect2
- ASNSD1 | c.1314G>T p.Q438H | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV53623378; called by muse, mutect2, varscan2
- ATCAY | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs371914915; called by muse, mutect2, varscan2
- ATG14 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs940692566, COSV55956070; called by muse, mutect2, varscan2
- ATP13A5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs143752942, COSV100665050; called by muse, mutect2, varscan2
- ATP2B3 | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54843906; called by muse, mutect2, varscan2
- ATP6AP1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); catalogued as COSV62340956; called by muse, mutect2, varscan2
- ATP6V0A4 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 40/479 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs894665573, COSV59474270; called by muse, mutect2
- BCL11A | c.2183G>A p.R728K (on ENST00000335712 / NM_001365609.1; = p.R762K on NM_022893.4) | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV59627543; called by muse, mutect2, varscan2
- BDP1 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs1356066618, COSV62430513; called by muse, mutect2, varscan2
- BPIFB2 | c.221T>G p.V74G | Missense Mutation (SNP) | VAF 82/324 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV50063711; called by muse, mutect2, varscan2
- BRD9 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60245926; called by muse, mutect2, varscan2
- BRINP1 | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV56296869; called by muse, mutect2, varscan2
- BRWD3 | c.5129G>A p.G1710E | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV100955589, COSV64746346; called by muse, mutect2, varscan2
- BRWD3 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748421788, COSV64746356; called by muse, mutect2, varscan2
- C19orf18 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771422741, COSV58705555; called by muse, mutect2, varscan2
- C1orf116 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs1347650051, COSV63943926; called by muse, mutect2, varscan2
- C2orf78 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68517139; called by muse, mutect2, varscan2
- C4B | c.3622G>A p.D1208N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV70313333; called by muse, mutect2, varscan2
- C5 | c.2498T>A p.V833D | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56325940; called by muse, mutect2, varscan2
- CACNG7 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV55813831; called by muse, mutect2, varscan2
- CALCOCO2 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51951579; called by muse, mutect2, varscan2
- CAPN6 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60694486; called by muse, mutect2, varscan2
- CAPZA3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as COSV56851099, COSV99856026; called by muse, mutect2, varscan2
- CASP8 | c.983G>A p.G328E (on ENST00000432109 / NM_033355.3; = p.G345E on NM_001228.4) | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51848755, COSV51861035; called by muse, mutect2, varscan2
- CBLB | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51424286; called by muse, mutect2, varscan2
- CCDC148 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs1428549409, COSV51757869; called by muse, mutect2, varscan2
- CCDC170 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53339256; called by muse, mutect2, varscan2
- CCDC30 | c.1892C>T p.S631F (on ENST00000340612; = p.S588F on NM_001080850.3) | Missense Mutation (SNP) | VAF 139/255 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59605437; called by muse, mutect2, varscan2
- CCDC30 | c.2203G>A p.E735K (on ENST00000340612; = p.E692K on NM_001080850.3) | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.091); catalogued as COSV59605442; called by muse, mutect2, varscan2
- CCDC54 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs865960669, COSV53758380, COSV53758641; called by muse, mutect2, varscan2
- CCDC62 | c.230-1G>A p.X77_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | catalogued as COSV53432272, COSV53436142; called by muse, mutect2, varscan2
- CCND2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54222217; called by muse, mutect2
- CCSER1 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 18/109 reads (17%) | catalogued as COSV61407451; called by muse, mutect2, varscan2
- CD163 | c.2312C>T p.S771F | Missense Mutation (SNP) | VAF 47/367 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63131143; called by muse, mutect2, varscan2
- CD1A | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs776795053, COSV56860452, COSV56861432, COSV99192208; called by muse, mutect2, varscan2
- CD209 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749104962, COSV52651807; called by muse, mutect2, varscan2
- CD22 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.723); catalogued as COSV50051103; called by muse, mutect2, varscan2
- CDC20B | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57051206; called by muse, mutect2, varscan2
- CDCP2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.601); catalogued as rs749868985, COSV61283316; called by muse, mutect2, varscan2
- CDH24 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs753411461, COSV57459974; called by muse, mutect2, varscan2
- CDH6 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as rs1239863031, COSV54067402; called by muse, mutect2, varscan2
- CDH8 | c.617T>A p.V206D | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54859081, COSV54876872; called by muse, mutect2, varscan2
- CDK8 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1360603716, COSV67420024; called by muse, mutect2, varscan2
- CDR1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267606368, COSV65164044; called by muse, mutect2, varscan2
- CELSR1 | c.4750A>G p.T1584A | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV53087029; called by muse, mutect2, varscan2
- CEMIP | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as COSV54990395; called by muse, mutect2, varscan2
- CFAP47 | c.4808G>A p.G1603E | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57972318; called by muse, mutect2, varscan2
- CFAP61 | c.2245C>T p.R749* | Nonsense Mutation (SNP) | VAF 34/227 reads (15%) | catalogued as rs984625585, COSV55624729; called by muse, mutect2, varscan2
- CFB | c.2089+1G>A p.X697_splice | Splice Site (SNP) | VAF 66/306 reads (22%) | catalogued as COSV64887477; called by muse, mutect2, varscan2
- CFHR4 | c.76C>G p.P26A (on ENST00000367416 / NM_001201551.2; = p.P27A on NM_006684.5) | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV52226937, COSV52229560; called by muse, mutect2, varscan2
- CFTR | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 18/236 reads (8%) | catalogued as CM941971, COSV50041069; called by muse, mutect2
- CHD6 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58555774; called by muse, mutect2, varscan2
- CHGB | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.617); catalogued as rs765892874, COSV66760087; called by muse, mutect2, varscan2
- CHKB | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56416022; called by muse, mutect2, varscan2
- CISH | c.257C>T p.S86F (on ENST00000348721 / NM_145071.4; = p.S103F on NM_013324.6) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62294737; called by muse, mutect2, varscan2
- CLCA4 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55367420; called by muse, mutect2, varscan2
- CLCN4 | c.1916C>T p.S639F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66465986; called by muse, mutect2
- CLDN18 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.946); catalogued as COSV51736257; called by muse, mutect2, varscan2
- CLEC4M | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758944528, COSV50217519; called by muse, mutect2, varscan2
- CLSTN3 | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV56935353; called by muse, mutect2, varscan2
- CLTRN | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as COSV66711770; called by muse, mutect2, varscan2
- CNGA1 | c.438G>A p.E146= | Splice Region (SNP) | VAF 15/94 reads (16%) | catalogued as COSV62053671; called by muse, mutect2, varscan2
- CNTN4 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV101281166; called by muse, mutect2, varscan2
- CNTN4 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV68573529; called by muse, mutect2, varscan2
- COCH | c.989G>A p.G330E (on ENST00000216361 / NM_001347720.1; = p.G265E on NM_004086.3) | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761209524, COSV53550276; called by muse, mutect2, varscan2
- COL19A1 | c.2768G>A p.G923E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867736301, COSV59569748; called by muse, mutect2, varscan2
- COL4A1 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as rs369960952, COSV65429741; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- COL4A2 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as rs1022756703, COSV64626940; called by muse, mutect2, varscan2
- COL6A6 | c.3238G>A p.G1080S | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs759591819, COSV62021952; called by muse, mutect2, varscan2
- CPA3 | c.69G>A p.R23= | Splice Region (SNP) | VAF 46/121 reads (38%) | catalogued as COSV56044618; called by muse, mutect2, varscan2
- CPED1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs374401699, COSV59999936; called by muse, mutect2
- CSF3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56640556; called by muse, mutect2, varscan2
- CTCF | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50464834; called by muse, mutect2, varscan2
- CTNNA2 | c.2816C>T p.S939L (on ENST00000402739 / NM_001282597.3; = p.S891L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/305 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1052098013, COSV58132864; called by muse, mutect2, varscan2
- CWH43 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV56937737; called by muse, mutect2, varscan2
- CYP2A13 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57837066; called by muse, mutect2, varscan2
- CYP3A7 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV60481107; called by muse, mutect2
- CYP4F8 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57853700; called by muse, mutect2, varscan2
- CYP7B1 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775806979, COSV59585812, COSV59593141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAB1 | c.1184C>T p.P395L (on ENST00000371231; = p.P362L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1445308748, COSV64691930, COSV64699763; called by muse, mutect2, varscan2
- DAB2 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100297757, COSV57913556; called by muse, mutect2, varscan2
- DCAF6 | c.1891T>C p.F631L (on ENST00000312263 / NM_001349778.1; = p.F651L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV56577199; called by muse, mutect2, varscan2
- DDX60L | c.2689C>T p.L897F | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52711441; called by muse, mutect2, varscan2
- DGKI | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55944254; called by muse, mutect2
- DHX8 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52252125; called by muse, mutect2, varscan2
- DISP2 | c.3436C>T p.R1146C | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs201590797, COSV51118941; called by muse, mutect2, varscan2
- DIXDC1 | c.1486C>T p.P496S (on ENST00000440460 / NM_001037954.4; = p.P285S on NM_033425.4) | Missense Mutation (SNP) | VAF 42/375 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.197); catalogued as rs371636063, COSV59461584; called by muse, mutect2, varscan2
- DMGDH | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as COSV54862369; called by muse, mutect2, varscan2
- DNAH3 | c.10489G>A p.G3497R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54514241; called by muse, mutect2, varscan2
- DNAH5 | c.10771G>A p.G3591R | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54216434; called by muse, mutect2, varscan2
- DNAH5 | c.10654G>A p.A3552T | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV54216451; called by muse, varscan2
- DNAJB8 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100048093; called by muse, mutect2, varscan2
- DNER | c.2102+2T>C p.X701_splice | Splice Site (SNP) | VAF 30/132 reads (23%) | catalogued as rs1437396827, COSV59163458; called by muse, mutect2, varscan2
- DOCK3 | c.5896G>A p.D1966N | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.107); catalogued as COSV56513642; called by muse, mutect2
- DOCK4 | c.5704C>T p.P1902S | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.979); catalogued as COSV70235326; called by muse, mutect2, varscan2
- DOP1A | c.6667T>C p.F2223L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV52708706; called by muse, mutect2, varscan2
- DSC1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV57144083; called by muse, mutect2, varscan2
- DSCAM | c.5626C>T p.P1876S | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68024382; called by muse, mutect2
- DSCAM | c.2579C>T p.S860F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68024389; called by muse, mutect2, varscan2
- DSCAM | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.556); catalogued as COSV68634132; called by muse, mutect2, varscan2
- DSG4 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867571290, COSV57390162; called by muse, mutect2
- DST | c.6931C>T p.H2311Y | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.178); catalogued as rs1212934934, COSV55007845, COSV99751273; called by muse, mutect2, varscan2
- DYRK4 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV50538447; called by muse, mutect2, varscan2
- DZIP3 | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 83/401 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as COSV64311660; called by muse, mutect2, varscan2
- EN2 | c.785A>T p.E262V | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52083004; called by muse, mutect2
- EPC2 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as rs764780426, COSV51542549; called by muse, mutect2, varscan2
- EPG5 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761998075, COSV56347792; called by muse, mutect2, varscan2
- EPHA5 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 81/196 reads (41%) | catalogued as COSV56633312; called by muse, mutect2, varscan2
- EPHA7 | c.2679G>A p.M893I | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV65180587; called by muse, mutect2
- ERCC3 | c.2224C>T p.R742W | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs368664230; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERV3-1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs753834087, COSV51426913, COSV51430277; called by muse, mutect2, varscan2
- ERV3-1 | c.825A>T p.L275F | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV51426917; called by muse, mutect2, varscan2
- ESRP1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64408805, COSV64412059; called by muse, mutect2, varscan2
- EXPH5 | c.4307G>A p.G1436E | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs779315623, COSV56200707; called by muse, mutect2
- EXT1 | c.1891C>T p.H631Y | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV65477412; called by muse, mutect2, varscan2
- EZH1 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as COSV70549061; called by muse, mutect2, varscan2
- F5 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV63122667; called by muse, mutect2, varscan2
- FAAH2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66506696; called by muse, mutect2, varscan2
- FAM122C | c.148A>T p.I50F | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV100888212; called by muse, mutect2
- FAM122C | c.149T>A p.I50N | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV100888214; called by muse, mutect2
- FAM199X | c.570G>A p.V190= | Splice Region (SNP) | VAF 17/97 reads (18%) | catalogued as COSV55433454; called by muse, mutect2, varscan2
- FAM210B | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 16/54 reads (30%) | catalogued as COSV57168116; called by muse, mutect2, varscan2
- FAM47C | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV63725535; called by muse, mutect2, varscan2
- FAM83F | c.1175C>G p.P392R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV100328835, COSV100329029; called by muse, mutect2, varscan2
- FAT4 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.701); catalogued as rs776704293, COSV101271897, COSV67897202; called by muse, mutect2, varscan2
- FAT4 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.517); catalogued as COSV101271900; called by muse, mutect2, varscan2
- FAT4 | c.5048T>C p.I1683T | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV67883823; called by muse, mutect2, varscan2
- FAT4 | c.10015A>C p.I3339L | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV58678827; called by muse, mutect2, varscan2
- FBN1 | c.1877G>A p.G626E | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100354042; called by muse, mutect2, varscan2
- FBN3 | c.5570G>A p.G1857E | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV54457581; called by muse, mutect2, varscan2
- FBN3 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs868829062, COSV54457590; called by muse, mutect2, varscan2
- FBXO15 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs753532685, COSV54044148; called by muse, mutect2, varscan2
- FBXO36 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs746894162, COSV52277429; called by muse, mutect2, varscan2
- FERD3L | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1406197403, COSV51762194, COSV51762637; called by muse, mutect2
- FGA | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.11); catalogued as COSV57392768, COSV57394829; called by muse, mutect2, varscan2
- FGD6 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs149396482; called by muse, mutect2, varscan2
- FGF6 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs1448230216, COSV57403639; called by muse, mutect2
- FGFR2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60640963; called by muse, mutect2, varscan2
- FGGY | c.981T>A p.N327K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58030462; called by muse, mutect2, varscan2
- FIBCD1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs573589654, COSV53393008; called by muse, mutect2, varscan2
- FILIP1 | c.2677A>G p.S893G | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52726645; called by muse, mutect2, varscan2
- FIS1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56191120; called by muse, mutect2, varscan2
- FKBP5 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV61880966; called by muse, mutect2, varscan2
- FLNB | c.3673G>C p.A1225P | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs371610564, COSV55875747; called by muse, mutect2, varscan2
- FLNC | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57953722; called by muse, mutect2
- FOLH1 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV57047611; called by muse, mutect2, varscan2
- FRAS1 | c.6700G>A p.E2234K | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53602113; called by muse, mutect2
- FRMD5 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1438640766, COSV68721190; called by muse, mutect2, varscan2
- GAB2 | c.1348G>T p.D450Y (on ENST00000361507 / NM_080491.3; = p.D412Y on NM_012296.3) | Missense Mutation (SNP) | VAF 64/702 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100416656, COSV60867008; called by muse, mutect2
- GAB4 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.931); catalogued as COSV68753484; called by muse, mutect2
- GABRB1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54976712; called by muse, mutect2, varscan2
- GALNT8 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs1437691590, COSV52896341; called by muse, mutect2, varscan2
- GCNA | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 68/563 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs761245998, COSV65466226; called by muse, varscan2
- GDF3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867390778, COSV61712125; called by muse, mutect2, varscan2
- GFRAL | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 39/327 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.422); catalogued as rs267601084, COSV61230090; called by muse, mutect2, varscan2
- GHR | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV50109348; called by muse, mutect2, varscan2
- GIMAP4 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.242); catalogued as COSV55431809, COSV55433315; called by muse, mutect2, varscan2
- GIMAP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs865805939, COSV61032437; called by muse, mutect2, varscan2
- GJB7 | c.65G>A p.W22* | Nonsense Mutation (SNP) | VAF 13/119 reads (11%) | catalogued as rs1344963005, COSV51529266; called by muse, mutect2, varscan2
- GLI2 | c.3124G>A p.D1042N (on ENST00000361492 / NM_001374353.1; = p.D1059N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as rs762818312, COSV58038867; called by muse, mutect2, varscan2
- GLUD2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV60151333; called by muse, mutect2, varscan2
- GMPS | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV55808737; called by muse, mutect2
- GP2 | c.695G>A p.R232K (on ENST00000381362 / NM_001007240.3; = p.R229K on NM_001502.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100221581, COSV56892923; called by muse, mutect2, varscan2
- GPATCH2 | c.977T>G p.L326* | Nonsense Mutation (SNP) | VAF 47/90 reads (52%) | catalogued as COSV65127492; called by muse, mutect2, varscan2
- GPC4 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV63697493; called by muse, mutect2, varscan2
- GPR158 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66267941, COSV66278746; called by muse, mutect2, varscan2
- GPRASP2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV59990821; called by muse, mutect2, varscan2
- GPX5 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV69079266; called by muse, mutect2, varscan2
- GRID2 | c.1347+1G>A p.X449_splice | Splice Site (SNP) | VAF 12/108 reads (11%) | catalogued as COSV56191077; called by muse, mutect2
- GRIN2A | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58027778; called by muse, mutect2, varscan2
- GRIN3A | c.700-1G>A p.X234_splice | Splice Site (SNP) | VAF 26/100 reads (26%) | catalogued as COSV62452302; called by muse, mutect2, varscan2
- GRM2 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.194); catalogued as COSV99622456; called by muse, mutect2, varscan2
- GRM2 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.799); catalogued as COSV99622458; called by muse, mutect2, varscan2
- GRM4 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1394218991, COSV65212171; called by muse, mutect2, varscan2
- GRM7 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63137735; called by muse, mutect2, varscan2
- GSPT2 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV61214012; called by muse, mutect2, varscan2
- GUCY2F | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 78/487 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV54300451; called by muse, mutect2, varscan2
- H4C3 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs1295273211, COSV58090285; called by muse, mutect2, varscan2
- HCN1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV57502869; called by mutect2, varscan2
- HCN1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57502899; called by muse, mutect2, varscan2
- HDAC9 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.973); catalogued as rs772831386, COSV67770758; called by muse, varscan2
- HEYL | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65721476; called by muse, mutect2, varscan2
- HHLA2 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as rs868050439, COSV63316629; called by muse, mutect2, varscan2
- HID1 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59351323; called by muse, mutect2
- HIVEP2 | c.5087C>A p.S1696Y | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50008391; called by muse, mutect2, varscan2
- HMX2 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as COSV60592550; called by muse, mutect2, varscan2
- HNF4A | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as rs1313425622, COSV57381457; called by muse, mutect2, varscan2
- HS3ST5 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57138016; called by muse, mutect2, varscan2
- HUWE1 | c.8469G>A p.M2823I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV53340987; called by muse, mutect2, varscan2
- HYDIN | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs866201822, COSV55478832; called by muse, mutect2, varscan2
- IFNK | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV51778639; called by muse, mutect2, varscan2
- IFT122 | c.1420C>T p.R474C (on ENST00000348417 / NM_052989.3; = p.R415C on NM_018262.4) | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs766295275, COSV56201756; called by muse, mutect2, varscan2
- IGKV1-5 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 81/308 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs777074286; called by muse, mutect2, varscan2
- IGKV3-7 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs766291549; called by muse, mutect2, varscan2
- IGLL1 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.99); catalogued as COSV50769864; called by muse, mutect2, varscan2
- IGSF10 | c.6661G>A p.D2221N | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56374741; called by muse, mutect2, varscan2
- IKZF4 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1324613344, COSV56267671; called by muse, mutect2, varscan2
- IL13RA2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1556509177, COSV99682877; called by muse, mutect2, varscan2
- IL18R1 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV52123825; called by muse, mutect2
- IL1R1 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52105577; called by muse, mutect2, varscan2
- IL2RG | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV52147892, COSV52148909; called by muse, mutect2, varscan2
- IL31RA | c.1385A>T p.E462V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV51680955; called by muse, mutect2, varscan2
- IL36A | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 99/403 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs770700259, COSV52082943, COSV52083194; called by muse, mutect2, varscan2
- IL3RA | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs753510585, COSV58430644; called by muse, mutect2
- ING4 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58554617; called by muse, mutect2, varscan2
- INHBA | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 148/537 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV54220669, COSV54221271; called by muse, mutect2, varscan2
- INTS1 | c.4862G>A p.W1621* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV67177047; called by muse, mutect2
- IRAK2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV56530359; called by muse, mutect2, varscan2
- IRX5 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV58058747, COSV58059047; called by muse, mutect2, varscan2
- ITGA4 | c.1836G>A p.M612I | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599106, COSV51998079, COSV52000901; called by muse, mutect2, varscan2
- ITGAX | c.705C>T p.V235= | Splice Region (SNP) | VAF 24/131 reads (18%) | catalogued as rs372032821, COSV51644200; called by muse, mutect2, varscan2
- ITGB2 | c.2313G>A p.W771* (on ENST00000302347; = p.W747* on NM_000211.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/119 reads (14%) | catalogued as rs868212330, COSV56609181; called by muse, mutect2, varscan2
- JAKMIP2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV54601422, COSV54601446; called by muse, mutect2, varscan2
- JUP | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs76416187, COSV60277574; called by muse, mutect2, varscan2
- KAT6A | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55904881; called by muse, mutect2, varscan2
- KCNA5 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV52904792, COSV99364250; called by muse, mutect2, varscan2
- KCNA6 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs1423494168, COSV54974060; called by muse, mutect2, varscan2
- KCNB2 | c.1791G>A p.M597I | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.129); catalogued as COSV73049640; called by muse, mutect2, varscan2
- KCND2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV58573780; called by muse, mutect2
- KCNV1 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs865900317, COSV52085529; called by muse, mutect2, varscan2
- KIAA1210 | c.5103G>A p.W1701* | Nonsense Mutation (SNP) | VAF 32/257 reads (12%) | catalogued as COSV68176530; called by muse, mutect2, varscan2
- KIFC1 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765880170, COSV65737434; called by muse, mutect2, varscan2
- KLF3 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54710320; called by muse, mutect2, varscan2
- KLHL12 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63042696; called by muse, mutect2, varscan2
- KMT2B | c.3676C>T p.H1226Y | Missense Mutation (SNP) | VAF 98/354 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55859506; called by muse, mutect2, varscan2
- KNTC1 | c.6034C>T p.P2012S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.531); catalogued as COSV61079558; called by muse, mutect2, varscan2
- KPRP | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV64221367; called by muse, mutect2, varscan2
- KRT13 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV55839604; called by muse, mutect2, varscan2
- KRT36 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100057435, COSV60203057; called by muse, mutect2, varscan2
- KRT37 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56656939; called by muse, mutect2, varscan2
- KRT83 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs769306649, COSV53339362; called by muse, mutect2, varscan2
- KRT9 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs918027925, COSV55852369; called by muse, mutect2, varscan2
- KSR2 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs765242951, COSV56666019; called by muse, mutect2, varscan2
- LACRT | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as COSV57688129; called by muse, mutect2, varscan2
- LCE3E | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 79/158 reads (50%) | catalogued as rs140473829; called by muse, varscan2
- LDLR | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV52942609; called by muse, mutect2
- LILRB2 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs576220286, COSV100079010; called by muse, varscan2
- LIMCH1 | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV58279647; called by muse, varscan2
- LIN28A | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs141345172, COSV54261260; called by muse, mutect2, varscan2
- LINGO1 | c.377T>A p.L126H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62436626; called by muse, mutect2
- LRCH2 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.899); catalogued as COSV57748480; called by muse, mutect2, varscan2
- LRP1 | c.11334C>T p.I3778= | Splice Region (SNP) | VAF 12/126 reads (10%) | catalogued as rs138595744; called by muse, mutect2
- LRP1B | c.12807G>A p.G4269= | Splice Region (SNP) | VAF 33/226 reads (15%) | catalogued as COSV67203342; called by muse, mutect2, varscan2
- LRP1B | c.8075G>A p.G2692E | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV67202092; called by muse, mutect2, varscan2
- LRP1B | c.5570G>A p.R1857K | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV67203350; called by muse, mutect2, varscan2
- LRP1B | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV67203355; called by muse, mutect2, varscan2
- LRP5 | c.4813C>T p.P1605S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as rs774727824, COSV99591442; called by muse, mutect2, varscan2
- LRRC58 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55229892; called by muse, mutect2, varscan2
- LRRCC1 | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64483127; called by muse, mutect2, varscan2
- LRRK2 | c.4189+2T>C p.X1397_splice | Splice Site (SNP) | VAF 5/84 reads (6%) | catalogued as COSV54149219; called by muse, mutect2
- LVRN | c.2176G>A p.V726I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV63496951; called by muse, mutect2, varscan2
- LY6G6F | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 63/471 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101011701; called by muse, mutect2, varscan2
- MAGEC1 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 54/425 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as rs766215209, COSV53570837; called by muse, mutect2, varscan2
- MAGEC1 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV53570847; called by muse, mutect2, varscan2
- MAP4K2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53642072; called by muse, mutect2, varscan2
- MAP9 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 24/143 reads (17%) | catalogued as COSV60904252; called by muse, mutect2, varscan2
- MARS1 | c.2100G>A p.R700= | Splice Region (SNP) | VAF 60/127 reads (47%) | catalogued as rs772399182, COSV56253641; called by muse, mutect2, varscan2
- MAST4 | c.1547G>A p.R516K (on ENST00000403625 / NM_001164664.2; = p.R327K on NM_015183.3) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV55120890; called by muse, mutect2
- MASTL | c.2263C>T p.H755Y (on ENST00000375940 / NM_001372029.1; = p.H754Y on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60910245; called by muse, mutect2, varscan2
- MCF2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV58481808; called by muse, mutect2, varscan2
- MCTP1 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV56510646; called by muse, mutect2, varscan2
- MCTP1 | c.1272+1G>A p.X424_splice | Splice Site (SNP) | VAF 4/39 reads (10%) | catalogued as COSV56510659; called by muse, mutect2, varscan2
- MDGA1 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs376834520; called by muse, mutect2, varscan2
- MDH2 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146302743, COSV59883985; called by muse, mutect2, varscan2
- MDM1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs150886543; called by muse, mutect2
- MED17 | c.1012+1G>A p.X338_splice | Splice Site (SNP) | VAF 22/329 reads (7%) | catalogued as COSV99315726; called by muse, mutect2
- MED17 | c.1012+2T>A p.X338_splice | Splice Site (SNP) | VAF 21/332 reads (6%) | catalogued as COSV99315727; called by muse, mutect2
- MEGF10 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs138372925, COSV57245118; called by muse, mutect2, varscan2
- MERTK | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54927313; called by muse, mutect2, varscan2
- MGAM | c.2839G>A p.G947R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746699052, COSV72074278; called by muse, mutect2, varscan2
- MICB | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.371); catalogued as COSV52856070; called by muse, mutect2, varscan2
- MICU3 | c.1085+1G>A p.X362_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV58845600; called by muse, mutect2, varscan2
- MID2 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV53308315; called by muse, mutect2, varscan2
- MLF1 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100576023, COSV63033135; called by muse, mutect2, varscan2
- MMEL1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV56520056; called by muse, mutect2, varscan2
- MMGT1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV60003072; called by muse, mutect2, varscan2
- MMP16 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54159018; called by muse, mutect2
- MMS22L | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51519427; called by muse, mutect2, varscan2
- MNDA | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs867226822, COSV63740382; called by muse, mutect2, varscan2
- MOV10L1 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV53169503; called by muse, mutect2, varscan2
- MRC2 | c.3104G>A p.W1035* | Nonsense Mutation (SNP) | VAF 34/234 reads (15%) | catalogued as COSV57638429; called by muse, mutect2, varscan2
- MROH2B | c.4327G>A p.D1443N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV68182472; called by muse, mutect2, varscan2
- MRPL20 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 74/323 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV61224135, COSV61224517; called by muse, mutect2, varscan2
- MRPL44 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV51312407; called by muse, mutect2, varscan2
- MTIF2 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as COSV55050976; called by muse, mutect2, varscan2
- MUC16 | c.25409C>T p.S8470L | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.047); catalogued as COSV67457410; called by muse, mutect2, varscan2
- MUC16 | c.25001C>T p.T8334I | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV67457421; called by muse, mutect2
- MUC16 | c.19243G>A p.E6415K | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV67457426; called by muse, mutect2, varscan2
- MUC16 | c.3578C>T p.P1193L | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1213793810, COSV67457442; called by muse, mutect2, varscan2
- MUC17 | c.6422C>T p.S2141L | Missense Mutation (SNP) | VAF 78/777 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV60284954; called by muse, mutect2, varscan2
- MXRA5 | c.6016G>A p.E2006K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV54230410; called by muse, mutect2, varscan2
- MXRA5 | c.5831C>T p.S1944L | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs137882293, COSV54230970; called by muse, mutect2, varscan2
- MXRA5 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV54230987, COSV99476431; called by muse, mutect2, varscan2
- MYH7 | c.4113G>A p.W1371* | Nonsense Mutation (SNP) | VAF 16/169 reads (9%) | catalogued as COSV62518044; called by muse, mutect2
- MYO15A | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as rs886052668; called by muse, mutect2
- MYO3A | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56323884; called by muse, mutect2, varscan2
- MYO3A | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56325923, COSV56351361; called by muse, mutect2, varscan2
- MYO7A | c.2171C>T p.T724I | Missense Mutation (SNP) | VAF 119/258 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68684234; called by muse, mutect2, varscan2
- MYO7B | c.4349C>T p.S1450F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV67346309; called by muse, mutect2, varscan2
- MYOZ2 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.023); catalogued as COSV100201833, COSV61084484; called by muse, mutect2, varscan2
- NAP1L2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as COSV65172359; called by muse, mutect2, varscan2
- NBEA | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV59773230; called by muse, mutect2, varscan2
- NDST4 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs749271707, COSV52112958; called by muse, mutect2, varscan2
- NDUFAF7 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.505); catalogued as COSV50017210; called by muse, mutect2, varscan2
- NEB | c.3755A>T p.N1252I | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1304204672, COSV51079818; called by muse, mutect2
- NEU1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV99998609; called by muse, mutect2, varscan2
- NHS | c.2114T>C p.L705P | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as COSV66273418; called by muse, mutect2
- NLRP5 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66761986; called by muse, mutect2, varscan2
- NLRP9 | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs752258952, COSV60461708; called by muse, mutect2, varscan2
- NME8 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs201987014, COSV52246843; called by muse, mutect2, varscan2
- NME9 | c.761C>T p.P254L (on ENST00000333911 / NM_001349024.2; = p.P193L on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as rs773561748, COSV58617741; called by muse, mutect2, varscan2
- NOL3 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); catalogued as rs1420596494, COSV50456899, COSV99220459; called by muse, mutect2
- NOS2 | c.3452C>T p.S1151L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV58222938; called by muse, mutect2, varscan2
- NOSTRIN | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58320507; called by muse, mutect2, varscan2
- NR3C2 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV60988170; called by muse, mutect2, varscan2
- NRK | c.1998G>A p.M666I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV54593131; called by muse, mutect2
- NRXN1 | c.3368G>A p.G1123E | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV58444788; called by muse, mutect2, varscan2
- NRXN1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV67999826; called by muse, mutect2, varscan2
- NRXN1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV68007646, COSV68007760, COSV68010120; called by muse, mutect2, varscan2
- NSD1 | c.6031C>T p.P2011S | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100728799, COSV61774027; called by muse, mutect2, varscan2
- NT5C1B | c.817G>A p.E273K (on ENST00000359846 / NM_001199086.2; = p.E213K on NM_033253.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs200906490, COSV100409784, COSV58394280; called by muse, varscan2
- NTRK3 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs375475747; called by muse, mutect2, varscan2
- NUP133 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV54569813; called by muse, mutect2, varscan2
- NUTM1 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV59216353; called by muse, mutect2, varscan2
- NUTM2A | c.2375G>A p.W792* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs559588134, COSV101095638; called by mutect2, varscan2
- NUTM2A | c.2376G>A p.W792* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as rs1239802604, COSV101095639; called by mutect2, varscan2
- OBSCN | c.1287G>C p.K429N | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.879); catalogued as COSV52760195; called by muse, mutect2, varscan2
- OBSCN | c.20314G>A p.D6772N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs770745639, COSV62257311; called by mutect2, varscan2
- ODF2 | c.1324G>A p.E442K (on ENST00000434106 / NM_153433.2; = p.E418K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV63546413; called by muse, mutect2, varscan2
- OR10G4 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs866856303, COSV57977250; called by muse, mutect2
- OR10G7 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 61/574 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs747619519, COSV57866579; called by muse, mutect2, varscan2
- OR10J3 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100171539, COSV59954043; called by muse, mutect2, varscan2
- OR10Q1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs755585068, COSV57470089; called by muse, mutect2, varscan2
- OR13C8 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs150858980, COSV58610395; called by muse, mutect2, varscan2
- OR1B1 | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV59171488; called by muse, mutect2, varscan2
- OR2K2 | c.448G>A p.D150N (on ENST00000374428; = p.D121N on NM_205859.2) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57016495; called by muse, mutect2, varscan2
- OR2L8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs763873339, COSV61726091; called by muse, mutect2, varscan2
- OR2T27 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs1333501102, COSV61283830; called by mutect2, varscan2
- OR4F6 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.044); catalogued as COSV61026566; called by muse, mutect2, varscan2
- OR52E4 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV57624367, COSV57626408; called by muse, mutect2, varscan2
- OR52N5 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs867329035, COSV57698652; called by muse, mutect2, varscan2
- OR52R1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs767975885, COSV61888040; called by muse, mutect2, varscan2
- OR5D13 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62332836; called by muse, mutect2, varscan2
- OR5H14 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as rs1240000589, COSV71193776; called by muse, mutect2, varscan2
- OR5M8 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.665); catalogued as COSV100510635, COSV59116433; called by muse, mutect2, varscan2
- OR6C65 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 134/309 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.924); catalogued as rs1213339398, COSV101110170, COSV101110211; called by mutect2, varscan2
- OR6K3 | c.821A>T p.Y274F (on ENST00000368146; = p.Y258F on NM_001005327.2) | Missense Mutation (SNP) | VAF 93/177 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs562743876, COSV63745489; called by muse, mutect2, varscan2
- OR8H3 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 96/699 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57908231; called by muse, mutect2, varscan2
- OTUD7A | c.1347G>A p.W449* (on ENST00000307050 / NM_001382637.1; = p.W442* on NM_130901.3) | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV61037506; called by muse, mutect2, varscan2
- OVCH2 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as COSV71952764; called by muse, mutect2, varscan2
- P3H2 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV60020266; called by muse, mutect2, varscan2
- PABPC4 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 123/191 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63293330; called by muse, mutect2, varscan2
- PABPC5 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV57040052; called by muse, mutect2, varscan2
- PAM | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57211745; called by muse, mutect2, varscan2
- PARD3B | c.3025C>A p.P1009T (on ENST00000406610 / NM_001302769.2; = p.P940T on NM_057177.7) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100592180; called by muse, mutect2, varscan2
- PARD3B | c.3026C>T p.P1009L (on ENST00000406610 / NM_001302769.2; = p.P940L on NM_057177.7) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100592181, COSV62510498; called by muse, mutect2, varscan2
- PCBP2 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); catalogued as COSV63728370; called by muse, mutect2, varscan2
- PCDH11X | c.3188A>T p.E1063V | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53455553; called by muse, mutect2, varscan2
- PCDH15 | c.4952A>G p.E1651G | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.045); catalogued as COSV57288195; called by muse, mutect2, varscan2
- PCDHA4 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.983); catalogued as COSV63539537, COSV63540299; called by muse, mutect2, varscan2
- PCDHA4 | c.2302G>A p.D768N | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs1554125251, COSV63538956; called by muse, mutect2, varscan2
- PCDHB5 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV50649339; called by muse, mutect2, varscan2
- PCDHGA4 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (1); catalogued as COSV53925503; called by muse, mutect2
- PCIF1 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59817078; called by muse, mutect2
- PCLO | c.4942A>G p.T1648A | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.389); catalogued as rs772549898, COSV61626298; called by muse, mutect2, varscan2
- PCSK5 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV65086980; called by muse, mutect2, varscan2
- PDE3A | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62970102; called by muse, mutect2, varscan2
- PDHA2 | c.738T>A p.F246L | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV54778280; called by muse, mutect2, varscan2
- PENK | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV59240769; called by muse, mutect2, varscan2
- PER1 | c.2131A>T p.K711* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as COSV57918563; called by muse, mutect2, varscan2
- PKD1L1 | c.8006G>A p.R2669Q | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs369504382; called by muse, mutect2, varscan2
- PKLR | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs140575553; called by muse, mutect2, varscan2
- PLCB4 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53798049; called by muse, mutect2, varscan2
- PLCXD2 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776771655, COSV67339127; called by muse, mutect2, varscan2
- PLD2 | c.240G>A p.K80= | Splice Region (SNP) | VAF 15/108 reads (14%) | catalogued as rs1183347106, COSV54005095; called by muse, mutect2, varscan2
- PLEC | c.10613C>T p.P3538L (on ENST00000322810 / NM_201380.4; = p.P3428L on NM_000445.5) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV59622103; called by muse, mutect2, varscan2
- PLEKHB1 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.07); catalogued as COSV57049296; called by muse, mutect2, varscan2
- PLPP4 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1477717291, COSV64827435; called by muse, mutect2, varscan2
- PLPP7 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV100952530; called by muse, mutect2, varscan2
- PLSCR4 | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV61607460, COSV61607720; called by muse, mutect2, varscan2
- PLXNB3 | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.933); catalogued as COSV62796630; called by muse, mutect2
- POLG | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51520621; called by muse, mutect2, varscan2
- PPBP | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs865869707, COSV56019654; called by muse, mutect2
- PPFIA2 | c.3604C>T p.P1202S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61027363; called by muse, mutect2, varscan2
- PPFIBP1 | c.128T>A p.M43K | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV57289792; called by muse, mutect2, varscan2
- PPP1R15A | c.1406A>G p.H469R | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs768034833, COSV52338670; called by muse, mutect2, varscan2
- PPP1R16B | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs866564102, COSV55376078; called by muse, mutect2, varscan2
- PPP1R9A | c.2546C>T p.T849I | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV56888086; called by muse, mutect2, varscan2
- PPP4R3B | c.2224C>T p.P742S (on ENST00000616407 / NM_001122964.3; = p.P657S on NM_020463.4) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV55403432; called by muse, mutect2, varscan2
- PPP6R2 | c.2684C>T p.P895L (on ENST00000216061 / NM_001365836.1; = p.P861L on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs150413435, COSV53291814; called by muse, mutect2, varscan2
- PRAMEF10 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs201689660; called by muse, mutect2, varscan2
- PRAMEF18 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 53/733 reads (7%) | catalogued as rs760126865; called by muse, mutect2
- PRB1 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 64/800 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.134); catalogued as rs200893556, COSV53703130; called by muse, mutect2
- PRDM14 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52571539; called by muse, mutect2, varscan2
- PRDM9 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.538); catalogued as COSV57004716; called by muse, mutect2, varscan2
- PRH1 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs1478002596, COSV101457477; called by muse, varscan2
- PRKN | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs529808032, COSV58203788, COSV58274029; called by muse, mutect2, varscan2
- PROX2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV71520018; called by muse, mutect2, varscan2
- PRSS1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 164/402 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs111033564, CM011001, COSV61192517; ClinVar: uncertain significance; called by muse, varscan2
- PSG5 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 99/637 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767117184, COSV61653481; called by muse, mutect2, varscan2
- PSG9 | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 53/433 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); catalogued as rs749464887, COSV52484382; called by muse, mutect2, varscan2
- PSTPIP2 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1463540987, COSV68957715; called by muse, mutect2
- PTPRB | c.3723G>A p.W1241* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as COSV54238000; called by muse, mutect2, varscan2
- PTPRG | c.2110G>A p.G704R | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs565961396, COSV55635567; called by muse, mutect2, varscan2
- PTPRR | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51728900; called by muse, mutect2, varscan2
- PURG | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53298418; called by muse, mutect2, varscan2
- RALYL | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101569561, COSV72819296; called by mutect2, varscan2
- RASGEF1A | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV65666815; called by muse, mutect2, varscan2
- RASGRP3 | c.1714G>A p.E572K (on ENST00000402538 / NM_001349975.2; = p.E571K on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV67821353; called by muse, mutect2, varscan2
- RBM12 | c.1005G>C p.L335F | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58290702; called by muse, mutect2, varscan2
- RELN | c.6944G>A p.G2315E | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV58994888; called by muse, mutect2, varscan2
- REST | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 102/771 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as COSV58360091; called by muse, mutect2, varscan2
- RFC1 | c.1985C>T p.S662F (on ENST00000381897 / NM_001363496.2; = p.S661F on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV62899100; called by muse, mutect2, varscan2
- RIBC1 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51447781; called by muse, mutect2, varscan2
- RIPK3 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV53474729, COSV99353225; called by muse, mutect2, varscan2
- RMI1 | c.1683G>A p.M561I | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV57935876; called by muse, mutect2
- RNASE4 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV59011845; called by muse, mutect2, varscan2
- RNF103 | c.1904T>A p.M635K | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV52894366; called by muse, mutect2, varscan2
- RP1 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV55109360; called by muse, mutect2, varscan2
- RPL13A | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV52618826; called by muse, mutect2, varscan2
- RRAD | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs764593765, COSV55334776; called by muse, mutect2, varscan2
- RSPRY1 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327464943, COSV68027501; called by muse, mutect2, varscan2
- RXFP1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57048487; called by muse, mutect2, varscan2
- RYR3 | c.14101G>A p.D4701N (on ENST00000389232; = p.D4702N on NM_001036.6) | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.239); catalogued as rs909959183, CM149398, COSV66783685; ClinVar: uncertain significance; called by muse, mutect2
- S100A8 | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 178/323 reads (55%) | catalogued as COSV100907091; called by muse, mutect2, varscan2
- SAMM50 | c.1177A>T p.T393S | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV63109646; called by muse, mutect2, varscan2
- SAMSN1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV53467549; called by muse, mutect2, varscan2
- SAP130 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs746530868, COSV52095999; called by muse, mutect2, varscan2
- SCML2 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as COSV52620060; called by muse, mutect2, varscan2
- SCN10A | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.124); catalogued as COSV71860926; called by muse, mutect2, varscan2
- SCN11A | c.4660G>A p.D1554N | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56565290; called by muse, mutect2, varscan2
- SCN1A | c.2672G>A p.G891E (on ENST00000303395 / NM_001202435.3; = p.G880E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868742933, COSV57662402; called by muse, mutect2, varscan2
- SCN1A | c.2539C>A p.L847I (on ENST00000303395 / NM_001202435.3; = p.L836I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV57665902; called by muse, mutect2, varscan2
- SCN1A | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs141188608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC31B | c.2136+1G>A p.X712_splice | Splice Site (SNP) | VAF 10/57 reads (18%) | catalogued as COSV64844084; called by muse, mutect2, varscan2
- SELP | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 165/297 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55250278; called by muse, mutect2, varscan2
- SEMA6A | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56710352; called by muse, mutect2, varscan2
- SETD2 | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 32/164 reads (20%) | catalogued as COSV57431254; called by muse, mutect2, varscan2
- SFTPD | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759296361, COSV64852839; called by muse, mutect2, varscan2
- SGCG | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54555984; called by muse, varscan2
- SGCZ | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 165/718 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs781344555, COSV66007485, COSV66027154; called by muse, varscan2
- SH3BP5 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV53743624; called by muse, mutect2, varscan2
- SH3KBP1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65640393, COSV65643538; called by muse, mutect2, varscan2
- SH3RF2 | c.2141C>T p.T714I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); catalogued as COSV63038293; called by muse, varscan2
- SHANK2 | c.5386G>A p.E1796K | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53583614, COSV53593003; called by muse, mutect2, varscan2
- SHROOM4 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV56787310; called by muse, mutect2, varscan2
- SIGLEC1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs778511177, COSV52461368; called by muse, mutect2, varscan2
- SIGLEC7 | c.45G>T p.R15S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV58315292; called by muse, varscan2
- SIN3A | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64582422, COSV64583736; called by muse, mutect2, varscan2
- SIPA1L3 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1334385092, COSV55911804, COSV55916187; called by muse, mutect2, varscan2
- SIPA1L3 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV55911811; called by muse, mutect2
- SLC10A2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55357973; called by muse, mutect2
- SLC15A2 | c.1923G>A p.M641I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55197157; called by muse, mutect2, varscan2
- SLC30A8 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV69969532; called by muse, mutect2, varscan2
- SLC35F6 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV60426259; called by muse, mutect2, varscan2
- SLC4A1AP | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1036943982, COSV58134311; called by muse, varscan2
- SLC4A5 | c.3175T>C p.F1059L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61026589; called by muse, mutect2, varscan2
- SLC52A1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54692700; called by muse, mutect2, varscan2
- SLC5A12 | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV54820326; called by muse, mutect2, varscan2
- SLC6A11 | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54392045; called by muse, mutect2, varscan2
- SLC6A5 | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs1407334436, COSV54225262; called by muse, mutect2, varscan2
- SLC7A11 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54929474; called by muse, mutect2
- SLC7A13 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs748074011, COSV52533423; called by muse, mutect2, varscan2
- SLC9A4 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV54832139; called by muse, mutect2, varscan2
- SLC9C1 | c.3056G>A p.W1019* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs757167008, COSV59887146; called by muse, mutect2, varscan2
- SLCO1B3 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748633316, COSV53935305; called by muse, mutect2, varscan2
- SLCO5A1 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867414896, COSV52652993, COSV52663499; called by muse, mutect2, varscan2
- SLITRK1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs144169256, COSV100999861, COSV65675021; called by muse, mutect2, varscan2
- SMC6 | c.3215G>A p.R1072K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV61173235; called by muse, mutect2, varscan2
- SMTNL1 | c.538+8G>A | Splice Region (SNP) | VAF 11/32 reads (34%) | catalogued as COSV67699481; called by muse, mutect2, varscan2
- SORCS3 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs780166617, COSV63806827; called by muse, mutect2, varscan2
- SPATA16 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 84/278 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV63528247; called by muse, mutect2, varscan2
- SPATA18 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs143324533; called by muse, mutect2, varscan2
- SPATA20 | c.932A>C p.D311A (on ENST00000356488 / NM_001258372.1; = p.D327A on NM_022827.4) | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50066258; called by muse, mutect2
- SPATA31E1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as COSV57790650; called by muse, mutect2, varscan2
- SPATA5L1 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59744367; called by muse, mutect2, varscan2
- SPHKAP | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV60870653; called by muse, mutect2, varscan2
- SPTA1 | c.1948G>A p.G650S | Missense Mutation (SNP) | VAF 97/193 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs201176207, COSV63751321; called by muse, mutect2, varscan2
- SRPX2 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.081); catalogued as COSV65933421; called by muse, mutect2, varscan2
- SSX3 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 184/612 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100035493, COSV53643765; called by muse, mutect2, varscan2
- ST18 | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777391759, COSV52489933; called by muse, mutect2, varscan2
- ST6GAL2 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | PolyPhen probably damaging (0.993); catalogued as COSV64527466, COSV64532737; called by muse, mutect2
- ST8SIA2 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 59/215 reads (27%) | PolyPhen probably damaging (0.996); catalogued as COSV51568400; called by muse, mutect2, varscan2
- STEAP1 | c.345C>A p.N115K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51881293; called by muse, mutect2
- STEAP4 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV57328472; called by muse, mutect2, varscan2
- STIL | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99680595; called by muse, mutect2, varscan2
- STIL | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV99680596; called by muse, mutect2, varscan2
- STK10 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV51572779; called by muse, mutect2
- STK26 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV61229305; called by muse, mutect2, varscan2
- STRC | c.4040C>T p.S1347F | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as COSV68461361; called by muse, mutect2, varscan2
- STYK1 | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV50012832; called by muse, mutect2, varscan2
- SYCP1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.026); catalogued as COSV65696314; called by muse, mutect2, varscan2
- SYNE1 | c.9241G>T p.V3081F (on ENST00000367255 / NM_182961.4; = p.V3088F on NM_033071.3) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99553902; called by muse, mutect2, varscan2
- SYNE1 | c.9240G>T p.L3080F (on ENST00000367255 / NM_182961.4; = p.L3087F on NM_033071.3) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV99553907; called by muse, mutect2, varscan2
- SYNJ2 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as rs759833654, COSV62896583; called by muse, mutect2, varscan2
- SYNPO2 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV61106092; called by muse, mutect2, varscan2
- SYT10 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs767119363, COSV57338723; called by muse, mutect2, varscan2
- SYT16 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV70855981; called by muse, mutect2, varscan2
- TAS1R3 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as rs760321025, COSV59562870; called by muse, mutect2, varscan2
- TBC1D9 | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV71307224; called by muse, mutect2, varscan2
- TBC1D9B | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV62281564; called by muse, mutect2, varscan2
- TBX22 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV64785501; called by muse, mutect2, varscan2
- TC2N | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV61746621; called by muse, mutect2, varscan2
- TCERG1 | c.2553A>C p.L851F | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.236); catalogued as COSV57036014; called by muse, varscan2
- TELO2 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs777809177, COSV51976891; called by muse, mutect2, varscan2
- TENM1 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64427141, COSV64428655; called by muse, mutect2, varscan2
- TENM2 | c.7256T>A p.L2419Q (on ENST00000518659 / NM_001122679.2; = p.L2180Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV69127207; called by muse, mutect2, varscan2
- TENM4 | c.3109G>A p.E1037K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV53619915; called by muse, mutect2, varscan2
- TEX14 | c.3005G>A p.G1002E (on ENST00000240361 / NM_001201457.2; = p.G996E on NM_031272.5) | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs867467416, COSV53614659; called by muse, mutect2, varscan2
- TF | c.1756A>T p.T586S | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV53919404; called by muse, mutect2, varscan2
- TFF1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52298323, COSV99367400; called by muse, mutect2
- TG | c.4937G>A p.R1646Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55071555; called by muse, mutect2
- TGM2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1185984509, COSV63931306; called by muse, mutect2
- TGM4 | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV56093454; called by muse, mutect2, varscan2
- TGM6 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs140181785, COSV52484286; called by muse, mutect2
- THOC2 | c.3785G>A p.S1262N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV55543766; called by muse, mutect2, varscan2
- THSD7A | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV70263110; called by muse, mutect2, varscan2
- THSD7B | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 39/190 reads (21%) | catalogued as rs1284002988, COSV55672323; called by muse, mutect2, varscan2
- TIMELESS | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57510409; called by muse, mutect2, varscan2
- TLE4 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1182490769, COSV54629801; called by muse, mutect2, varscan2
- TM7SF2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 84/409 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV54206763; called by muse, mutect2, varscan2
- TMC2 | c.2375A>T p.K792I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62651519; called by muse, mutect2, varscan2
- TMC7 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs867702845, COSV58582515; called by muse, mutect2, varscan2
- TMC8 | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV59209191; called by muse, mutect2
- TMEM131 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | catalogued as COSV99486588; called by muse, mutect2, varscan2
- TMEM132B | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.085); catalogued as rs757718701, COSV54749643; called by muse, mutect2, varscan2
- TMEM161B | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV56930356, COSV56932727; called by muse, mutect2, varscan2
- TMEM175 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs770130595, COSV53278238; called by muse, mutect2, varscan2
- TMEM63C | c.1188G>A p.W396* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV53602725; called by muse, mutect2, varscan2
- TMEM71 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63457023; called by muse, mutect2, varscan2
- TMPRSS15 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369844272; called by muse, mutect2, varscan2
- TNR | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs775102963, COSV54878733; called by muse, mutect2, varscan2
- TNXB | c.7694C>T p.S2565F (on ENST00000647633; = p.S2318F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64476810; called by muse, mutect2, varscan2
- TOP2A | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 124/422 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV70732385; called by muse, mutect2, varscan2
- TOX | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs145034555; called by muse, mutect2, varscan2
- TRAFD1 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 137/310 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.663); catalogued as rs201346904, COSV57504001; called by muse, mutect2, varscan2
- TRAV5 | c.122T>C p.I41T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1246904452; called by muse, mutect2, varscan2
- TRERF1 | c.2620T>G p.L874V | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.162); catalogued as COSV61669625; called by muse, mutect2, varscan2
- TRIM48 | c.358T>C p.C120R | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233006488, COSV70161262; called by muse, mutect2, varscan2
- TRIML2 | c.701T>C p.L234S | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.129); catalogued as COSV58715486; called by muse, mutect2, varscan2
- TRPC6 | c.1126A>T p.K376* | Nonsense Mutation (SNP) | VAF 151/285 reads (53%) | catalogued as COSV60252601; called by muse, mutect2, varscan2
- TRPC7 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1160045860, COSV61456356; called by muse, mutect2, varscan2
- TSGA10 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 34/154 reads (22%) | catalogued as COSV61822211; called by muse, mutect2, varscan2
- TSPOAP1 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52106574; called by muse, mutect2, varscan2
- TTBK2 | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV51158761; called by muse, mutect2, varscan2
- TTC13 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV64168277; called by muse, mutect2, varscan2
- TTC26 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1260374560, COSV58270708; called by muse, mutect2
- TTC29 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1053527338, COSV57271919; called by muse, mutect2, varscan2
- TTN | c.76012C>T p.P25338S (on ENST00000591111; = p.P17914S on NM_003319.4) | Missense Mutation (SNP) | VAF 46/149 reads (31%) | PolyPhen probably damaging (0.998); catalogued as COSV59976817; called by muse, mutect2, varscan2
- TTN | c.56524C>T p.R18842C (on ENST00000591111; = p.R11418C on NM_003319.4) | Missense Mutation (SNP) | VAF 25/196 reads (13%) | PolyPhen probably damaging (0.966); catalogued as rs770139489, COSV59976848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.47296G>A p.E15766K (on ENST00000591111; = p.E8342K on NM_003319.4) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | PolyPhen probably damaging (0.994); catalogued as COSV59976880; called by muse, mutect2, varscan2
- TTN | c.21749G>A p.G7250E (on ENST00000591111; = p.G6323E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/345 reads (25%) | PolyPhen benign (0.011); catalogued as rs764311341, COSV59977029; called by muse, mutect2, varscan2
- TTN | c.7782G>A p.M2594I (on ENST00000591111; = p.M2548I on NM_003319.4) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | PolyPhen benign (0.137); catalogued as COSV59977055; called by muse, mutect2, varscan2
- TTPA | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV52646260; called by muse, mutect2, varscan2
- TUB | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV59488431, COSV59489082; called by muse, mutect2, varscan2
- TUFM | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV57948661; called by muse, mutect2, varscan2
- UACA | c.3802G>A p.E1268K | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV59854824; called by muse, mutect2, varscan2
- UBE2J2 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV59572081; called by muse, mutect2, varscan2
- UBR4 | c.14971C>T p.P4991S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64386326; called by muse, mutect2, varscan2
- UGT2B28 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV59431371; called by muse, mutect2, varscan2
- UNC13A | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV53192399; called by muse, mutect2, varscan2
- USH2A | c.5705G>A p.G1902E | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV56352079; called by muse, mutect2, varscan2
- USP21 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV57087667; called by muse, mutect2, varscan2
- UTRN | c.8552C>T p.S2851F | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs762992139, COSV62308771; called by muse, mutect2
- VPS35L | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV51980537; called by muse, mutect2, varscan2
- WNK1 | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60029657; called by muse, mutect2, varscan2
- WNK1 | c.4801C>T p.P1601S (on ENST00000315939 / NM_018979.4; = p.P1354S on NM_014823.3) | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV60029691; called by muse, mutect2, varscan2
- WNK3 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100671685, COSV63612965; called by muse, mutect2, varscan2
- WNK4 | c.3432-1G>A p.X1144_splice | Splice Site (SNP) | VAF 15/115 reads (13%) | catalogued as COSV55903003; called by muse, mutect2, varscan2
- WWC1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1175949905, COSV54649137; called by muse, mutect2, varscan2
- XIRP2 | c.9905G>A p.R3302K (on ENST00000628543; = p.R3477K on NM_152381.6) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54692278; called by muse, mutect2, varscan2
- YBX3 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54385076, COSV54386658; called by muse, mutect2, varscan2
- YEATS2 | c.3565A>G p.K1189E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59363920; called by muse, mutect2, varscan2
- YTHDC1 | c.1606C>T p.R536* (on ENST00000344157 / NM_001031732.4; = p.R518* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV60009683; called by muse, mutect2, varscan2
- ZAN | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as rs199814972, COSV61807480; called by muse, mutect2
- ZBED9 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV71729287; called by muse, mutect2, varscan2
- ZBTB25 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV67198519; called by muse, mutect2, varscan2
- ZCCHC12 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59571304; called by muse, mutect2
- ZDHHC17 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58350015; called by muse, mutect2, varscan2
- ZFHX4 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as rs1363628365, COSV50663542; called by muse, mutect2, varscan2
- ZFYVE28 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs151169783; called by muse, mutect2, varscan2
- ZHX3 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 51/356 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201358446, COSV58382334; called by muse, mutect2, varscan2
- ZNF208 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.574); catalogued as COSV68103244; called by muse, mutect2, varscan2
- ZNF248 | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs762542929, COSV61997436, COSV61998145; called by muse, mutect2, varscan2
- ZNF284 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV69690836; called by muse, mutect2, varscan2
- ZNF285 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.338); catalogued as rs763608904, COSV58408515; called by muse, mutect2, varscan2
- ZNF41 | c.2305C>G p.H769D | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57441967; called by muse, mutect2, varscan2
- ZNF440 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58370727; called by muse, mutect2, varscan2
- ZNF443 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV56891135; called by muse, mutect2, varscan2
- ZNF493 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs143136118, COSV100828492, COSV62749722; called by muse, mutect2, varscan2
- ZNF507 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as rs746739319, COSV61330670; called by muse, mutect2, varscan2
- ZNF530 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 15/133 reads (11%) | catalogued as rs776560737, COSV100252406; called by muse, mutect2, varscan2
- ZNF560 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs747315246, COSV56866069; called by muse, mutect2, varscan2
- ZNF560 | c.530-1G>A p.X177_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV56867007, COSV56868860; called by muse, mutect2, varscan2
- ZNF709 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.909); catalogued as COSV67194471; called by muse, mutect2, varscan2
- ZNF776 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV57814971; called by muse, mutect2, varscan2
- ZNF790 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as COSV63212226; called by muse, mutect2, varscan2
- ZP1 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99612188; called by muse, mutect2, varscan2
- ZP4 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV63911619; called by muse, mutect2, varscan2
- ZPLD1 | c.696G>A p.M232I (on ENST00000466937 / NM_001329788.1; = p.M248I on NM_175056.2) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV60352786; called by muse, mutect2, varscan2
- ZSCAN31 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 91/200 reads (46%) | catalogued as rs757653477, COSV60180213; called by muse, mutect2, varscan2
- ZXDA | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV62387743; called by muse, mutect2, varscan2
- ACACA | c.6959G>A p.G2320D | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- AMY1A | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); called by mutect2, varscan2
- IGHG2 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV3-20 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2
- N4BP2L1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAX4 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- PRKCZ | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLC6A6 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- SUPT20HL1 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TMC1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TRAV3 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- WASHC2A | c.2900C>T p.A967V | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ACOT9 | c.1272C>T p.S424= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV60537298; called by muse, mutect2, varscan2
- ADA2 | c.429C>T p.I143= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as COSV52831007; called by muse, mutect2, varscan2
- ADCY8 | c.595C>T p.L199= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV53903029; called by muse, mutect2, varscan2
- ADCYAP1 | c.39C>T p.V13= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as COSV52486121, COSV99327581; called by muse, mutect2, varscan2
- ADGRE3 | c.510G>A p.S170= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as rs143842724, COSV53729630, COSV99506243; called by muse, mutect2, varscan2
- ADGRG4 | c.5730G>A p.E1910= | Silent (SNP) | VAF 39/254 reads (15%) | catalogued as COSV54953155; called by muse, mutect2, varscan2
- ADGRL4 | c.1968G>A p.Q656= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as rs779288246, COSV66060895, COSV66061088; called by muse, mutect2, varscan2
- AFF2 | c.777A>G p.L259= | Silent (SNP) | VAF 42/350 reads (12%) | catalogued as COSV60660545; called by muse, mutect2, varscan2
- AGBL1 | c.1332C>T p.S444= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV66854075; called by muse, mutect2
- AKAP4 | c.1224G>A p.K408= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV62074138; called by muse, mutect2, varscan2
- AQP8 | c.144C>T p.F48= | Silent (SNP) | VAF 57/313 reads (18%) | catalogued as COSV54844723; called by muse, mutect2, varscan2
- ARHGAP21 | c.5736C>T p.S1912= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as COSV57604470; called by muse, mutect2, varscan2
- ASB15 | c.627T>C p.F209= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs1387142460, COSV51924988; called by muse, varscan2
- ATF4 | c.513C>A p.S171= | Silent (SNP) | VAF 58/231 reads (25%) | catalogued as COSV57478434; called by muse, mutect2, varscan2
- ATP1A3 | c.913C>T p.L305= (on ENST00000545399 / NM_001256214.2; = p.L292= on NM_152296.5) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV57486610; called by muse, mutect2, varscan2
- ATP1A3 | c.447C>T p.F149= (on ENST00000545399 / NM_001256214.2; = p.F136= on NM_152296.5) | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV57486621; called by muse, mutect2, varscan2
- ATP1A4 | c.348C>T p.A116= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as rs1256835197, COSV63626053; called by muse, mutect2, varscan2
- ATP2A2 | c.1923C>T p.F641= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs779387152, COSV57875237; called by muse, mutect2, varscan2
- BBOX1 | c.231A>C p.T77= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV54190382; called by muse, mutect2, varscan2
- BIN1 | c.1563C>T p.F521= (on ENST00000316724 / NM_001320642.1; = p.F382= on NM_004305.4) | Silent (SNP) | VAF 20/178 reads (11%) | catalogued as COSV52117254; called by muse, mutect2, varscan2
- BIRC7 | c.894C>T p.S298= (on ENST00000217169 / NM_139317.3; = p.S280= on NM_022161.4) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV53900796; called by muse, mutect2, varscan2
- BSPRY | c.285G>A p.K95= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV65242490; called by muse, mutect2, varscan2
- C2orf16 | c.678G>A p.E226= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV104435198, COSV68645726; called by muse, mutect2, varscan2
- C6 | c.2181C>T p.S727= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV54708229; called by muse, mutect2, varscan2
- C6 | c.1899C>T p.V633= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs769453887, COSV54708239; called by muse, mutect2, varscan2
- C8orf34 | c.1437G>A p.L479= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs147613223; called by muse, mutect2, varscan2
- CACNA1D | c.6396C>T p.D2132= (on ENST00000350061 / NM_001128840.3; = p.D2152= on NM_000720.4) | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as COSV55442949; called by muse, mutect2
- CALN1 | c.447G>A p.T149= (on ENST00000329008 / NM_001017440.3; = p.T191= on NM_031468.4) | Silent (SNP) | VAF 18/215 reads (8%) | catalogued as rs766714139, COSV61119273; called by muse, mutect2
- CAMTA1 | c.4330C>T p.L1444= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV57892713; called by muse, mutect2, varscan2
- CARD8 | c.936C>T p.S312= (on ENST00000651546 / NM_001184900.3; = p.S262= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as rs753348450, COSV62873233; called by muse, mutect2, varscan2
- CARF | c.234C>T p.F78= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as COSV57547149; called by muse, mutect2, varscan2
- CARMIL1 | c.2757C>T p.S919= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV61515975; called by muse, mutect2
- CCDC178 | c.1620C>T p.L540= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV55767791; called by muse, mutect2, varscan2
- CCDC178 | c.1098G>A p.E366= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV55767812; called by muse, mutect2
- CCL8 | c.123G>A p.R41= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV67013909; called by muse, mutect2, varscan2
- CD14 | c.147C>T p.F49= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV57370547; called by muse, mutect2, varscan2
- CDC42BPG | c.1245G>A p.L415= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV61346600; called by muse, mutect2, varscan2
- CDCP1 | c.1275G>A p.R425= | Silent (SNP) | VAF 34/306 reads (11%) | catalogued as COSV56104630; called by muse, mutect2, varscan2
- CDH16 | c.519C>T p.A173= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV55335916; called by muse, mutect2, varscan2
- CDX4 | c.84G>A p.G28= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs886601996, COSV65171565, COSV65171913; called by muse, mutect2, varscan2
- CEACAM20 | c.1437G>A p.R479= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV57600797; called by muse, mutect2
- CFAP221 | c.1593G>A p.K531= | Silent (SNP) | VAF 72/256 reads (28%) | catalogued as COSV54656062; called by muse, varscan2
- CHKB | c.936T>C p.F312= | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as COSV56416019; called by muse, mutect2, varscan2
- CIT | c.1032C>T p.G344= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as COSV55865212; called by muse, mutect2, varscan2
- CLCC1 | c.522C>T p.F174= (on ENST00000356970 / NM_001377464.1; = p.F124= on NM_015127.5) | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs138361021; called by muse, mutect2, varscan2
- CLCNKA | c.1956C>T p.N652= | Silent (SNP) | VAF 102/254 reads (40%) | catalogued as COSV58891117; called by muse, mutect2, varscan2
- CNGA3 | c.2028C>T p.P676= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV55623574; called by muse, mutect2, varscan2
- CNPPD1 | c.1218C>T p.F406= | Silent (SNP) | VAF 37/193 reads (19%) | catalogued as rs767238818, COSV55406274; called by muse, mutect2, varscan2
- CNTNAP4 | c.894G>A p.R298= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV56673864; called by muse, mutect2
- CNTNAP4 | c.2919G>A p.G973= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV56669432; called by muse, mutect2, varscan2
- COL5A1 | c.1896C>T p.F632= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs376478864; ClinVar: conflicting interpretations of pathogenicity / benign; called by muse, mutect2, varscan2
- COL6A2 | c.591G>A p.K197= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV56002612; called by muse, mutect2, varscan2
- CPAMD8 | c.1155C>T p.P385= (on ENST00000651564; = p.P338= on NM_015692.5) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs771180305, COSV52231596; called by muse, mutect2
- CPZ | c.1914C>T p.F638= (on ENST00000360986 / NM_001014447.3; = p.F627= on NM_003652.3) | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs765210808, COSV59922422; called by muse, mutect2, varscan2
- CR1L | c.114G>A p.P38= | Silent (SNP) | VAF 80/157 reads (51%) | catalogued as rs757581505, COSV54324774; called by muse, mutect2, varscan2
- CRTC2 | c.891C>T p.A297= | Silent (SNP) | VAF 98/169 reads (58%) | catalogued as COSV57841989; called by muse, mutect2, varscan2
- CTR9 | c.819C>T p.N273= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs763594613, COSV100797260; called by mutect2, varscan2
- CX3CR1 | c.393C>T p.I131= | Silent (SNP) | VAF 64/192 reads (33%) | catalogued as rs1422686529, COSV64193514; called by muse, mutect2, varscan2
- CYP26A1 | c.1071G>C p.G357= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV56417695; called by muse, mutect2, varscan2
- DENND2A | c.2142C>T p.I714= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV52049651; called by muse, mutect2, varscan2
- DNAH17 | c.9648C>T p.A3216= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs779637890, COSV67751952; called by muse, mutect2, varscan2
- DNAH5 | c.12324C>T p.F4108= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV54201346; called by muse, mutect2, varscan2
- DNAH8 | c.8628C>T p.I2876= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV59436735; called by muse, mutect2, varscan2
- DNAJB11 | c.723C>T p.F241= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54002261; called by muse, mutect2, varscan2
- DNAJB8 | c.81C>T p.A27= | Silent (SNP) | VAF 35/301 reads (12%) | catalogued as COSV100048094; called by muse, mutect2, varscan2
- DNAJC5B | c.313C>T p.L105= | Silent (SNP) | VAF 48/180 reads (27%) | catalogued as COSV52536704; called by muse, mutect2, varscan2
- DOCK8 | c.3195G>A p.R1065= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs781062154, COSV101209802, COSV101209975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK9 | c.4338G>A p.T1446= (on ENST00000376460 / NM_001366676.2; = p.T1447= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1403298114, COSV59624850; called by muse, mutect2, varscan2
- DSP | c.915C>T p.I305= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs148395326; ClinVar: likely benign; called by muse, mutect2, varscan2
- DST | c.14802C>T p.T4934= (on ENST00000361203 / NM_001374722.1; = p.T2522= on NM_015548.5) | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as COSV55007334; called by muse, mutect2, varscan2
- DYSF | c.5334C>T p.I1778= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs727503913, COSV50295252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.384C>T p.L128= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs767736751, COSV56181720; called by muse, mutect2, varscan2
- EEF2KMT | c.600T>C p.N200= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as rs755536775, COSV52157148; called by muse, mutect2, varscan2
- EHHADH | c.819C>T p.F273= | Silent (SNP) | VAF 25/273 reads (9%) | catalogued as rs201465186; called by muse, mutect2
- EIF4A2 | c.319T>C p.L107= | Silent (SNP) | VAF 54/285 reads (19%) | catalogued as COSV56216450; called by muse, mutect2, varscan2
- ELMO1 | c.2166C>T p.F722= | Silent (SNP) | VAF 44/168 reads (26%) | catalogued as COSV60300606; called by muse, mutect2, varscan2
- EMSY | c.3594G>A p.A1198= | Silent (SNP) | VAF 33/204 reads (16%) | catalogued as rs761026121, COSV58258945; called by muse, mutect2, varscan2
- ENTHD1 | c.1719T>C p.L573= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV57318878; called by muse, mutect2, varscan2
- ERICH3 | c.87G>A p.R29= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV58603555; called by muse, mutect2, varscan2
- ERLIN2 | c.882G>A p.K294= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV52420278; called by muse, mutect2, varscan2
- EZH2 | c.885C>T p.F295= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV57450256; called by muse, mutect2, varscan2
- F11R | c.339G>A p.E113= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV57036822; called by muse, mutect2, varscan2
- FAM135B | c.1140G>A p.R380= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as COSV52716618; called by muse, mutect2, varscan2
- FAM237A | c.294C>T p.F98= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV69304990; called by muse, mutect2, varscan2
- FAM83F | c.1176C>T p.P392= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100328838, COSV60999655; called by muse, mutect2, varscan2
- FBN1 | c.1878G>A p.G626= | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as CD123576, COSV100354040; called by muse, mutect2, varscan2
- FCN2 | c.885G>A p.S295= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs150154280; called by muse, mutect2, varscan2
266 further variants in this file (0 protein-altering or splice-affecting, 245 silent, 21 other) are not listed here.
